Somatic mutation profile of tumor specimen C3N-00436-01 (aliquot CPT0077860006) from CPTAC case C3N-00436, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 69.6 years (25,422 days).
Specimen C3N-00436-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85e9494f-27e6-4ed8-8178-42c298291ca8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00436-31 (Blood Derived Normal), aliquot CPT0077920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1eb8df6f-d0fc-4099-b146-1d1a26fd3da9

The open-access MAF lists 48 somatic variants for this specimen: 26 protein-altering or splice-affecting, 14 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 14, Nonsense Mutation 4, Intron 4, RNA 2, 3'UTR 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 31/346 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 47/433 reads (11%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL6A3 | c.7416G>C p.K2472N | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as COSV99797989; called by muse, mutect2
- DBN1 | c.1004C>T p.T335M | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.271); catalogued as rs748335051; called by muse, mutect2
- DOCK2 | c.2750G>A p.R917Q | Missense Mutation (SNP) | VAF 28/288 reads (10%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs765098414, COSV56969381, COSV56987689; called by muse, mutect2
- ERBB4 | c.2512C>T p.R838* | Nonsense Mutation (SNP) | VAF 32/271 reads (12%) | catalogued as rs1423325504, COSV61472598; called by muse, mutect2, varscan2
- EVC2 | c.1820C>T p.T607I | Missense Mutation (SNP) | VAF 21/303 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.039); catalogued as rs1044253878; called by muse, mutect2
- KRT13 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.479); catalogued as rs138885186; called by muse, mutect2
- METTL27 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs782150735; called by muse, mutect2
- MTRF1L | c.556G>T p.G186C | Missense Mutation (SNP) | VAF 24/368 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779401000; called by muse, mutect2
- NLGN4X | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 39/346 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs751945904, CM057847, COSV52015100; called by muse, mutect2, varscan2
- NOS2 | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as rs1436077571; called by muse, mutect2, varscan2
- PRRG3 | c.56G>A p.R19H | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs1309178547; called by muse, mutect2, varscan2
- RALGAPA1 | c.5995C>T p.R1999* | Nonsense Mutation (SNP) | VAF 20/200 reads (10%) | catalogued as rs772869468, COSV51878805; called by muse, mutect2
- SLC4A10 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs759420527, COSV55768636; called by muse, mutect2
- SLC8A3 | c.797G>A p.R266H | Missense Mutation (SNP) | VAF 36/458 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs375603290; called by muse, mutect2
- TUBAL3 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.178); catalogued as rs140777769; called by muse, mutect2, varscan2
- UNC45A | c.2212G>A p.V738I | Missense Mutation (SNP) | VAF 19/226 reads (8%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.979); catalogued as rs1370216230; called by muse, mutect2
- VIT | c.1523C>T p.T508M (on ENST00000389975 / NM_001177969.1; = p.T523M on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/227 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs182729056, COSV101007796, COSV99061748; called by muse, mutect2, varscan2
- XDH | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 35/517 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs745346331, COSV65148108; called by muse, mutect2
- DBX2 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.471); called by muse, mutect2
- EPRS1 | c.3943C>T p.L1315F | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.519); called by muse, varscan2
- MARK2 | c.235-2A>T p.X79_splice | Splice Site (SNP) | VAF 26/258 reads (10%) | called by muse, mutect2
- NEB | c.7795A>T p.K2599* | Nonsense Mutation (SNP) | VAF 42/524 reads (8%) | called by muse, mutect2
- NUFIP2 | c.1153T>G p.S385A | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.007); called by muse, mutect2
- PKN2 | c.2737C>T p.H913Y | Missense Mutation (SNP) | VAF 24/312 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- ARID5B | c.2703G>A p.T901= | Silent (SNP) | VAF 5/59 reads (8%) | catalogued as rs1456259035; called by muse, mutect2
- CAMSAP2 | c.1218A>C p.S406= (on ENST00000236925 / NM_001297707.2; = p.S395= on NM_203459.3) | Silent (SNP) | VAF 14/266 reads (5%) | called by muse, mutect2
- DCAF12L2 | c.1024C>A p.R342= | Silent (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- HNRNPK | c.1290C>T p.S430= | Silent (SNP) | VAF 16/151 reads (11%) | catalogued as rs115346013, COSV61090799; called by muse, mutect2, varscan2
- KIF4A | c.2946G>A p.Q982= | Silent (SNP) | VAF 29/308 reads (9%) | called by muse, mutect2, varscan2
- L1CAM | c.795C>T p.I265= | Silent (SNP) | VAF 40/459 reads (9%) | catalogued as rs141383999; called by muse, mutect2
- LSM2 | c.183C>T p.F61= | Silent (SNP) | VAF 30/363 reads (8%) | called by muse, mutect2
- NPC1 | c.1620A>G p.P540= | Silent (SNP) | VAF 67/527 reads (13%) | called by muse, mutect2, varscan2
- OR8B12 | c.354G>A p.A118= | Silent (SNP) | VAF 23/202 reads (11%) | catalogued as rs764768343, COSV60911867; called by muse, mutect2, varscan2
- PAPSS2 | c.990C>T p.D330= | Silent (SNP) | VAF 53/561 reads (9%) | catalogued as rs183111777; called by muse, mutect2
- RIMS1 | c.3714G>A p.A1238= | Silent (SNP) | VAF 20/135 reads (15%) | catalogued as rs373917034; called by muse, mutect2, varscan2
- SNTG2 | c.600G>A p.S200= | Silent (SNP) | VAF 23/192 reads (12%) | catalogued as rs141600263, COSV57967650, COSV57994294; called by muse, mutect2, varscan2
- TATDN1 | c.708A>G p.K236= | Silent (SNP) | VAF 18/188 reads (10%) | called by muse, mutect2
- ZNF831 | c.4845T>C p.R1615= | Silent (SNP) | VAF 12/258 reads (5%) | called by muse, mutect2
- AKAP14 | c.261+27G>T | Intron (SNP) | VAF 26/324 reads (8%) | called by muse, mutect2
- ARMCX4 | c.1038+726C>G | Intron (SNP) | VAF 21/272 reads (8%) | called by muse, mutect2
- DCHS2 | n.3046C>T | RNA (SNP) | VAF 20/181 reads (11%) | catalogued as rs774677154, COSV59717808; called by muse, mutect2, varscan2
- JAKMIP3 | c.*288G>A | 3'UTR (SNP) | VAF 21/137 reads (15%) | catalogued as rs779013303; called by muse, mutect2, varscan2
- MARCHF10 | c.383-2376A>G | Intron (SNP) | VAF 20/230 reads (9%) | called by muse, mutect2
- MTMR10 | c.-34C>T | 5'UTR (SNP) | VAF 11/140 reads (8%) | called by muse, mutect2
- SERPINA13P | n.1151A>T | RNA (SNP) | VAF 19/216 reads (9%) | called by muse, mutect2
- UBE2D2 | c.24+464G>A | Intron (SNP) | VAF 22/212 reads (10%) | called by muse, mutect2
